Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4294, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4294-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Stomach Tumor size: 5 x 4 x 2 cm Tumor features: Ulcerated
Histologic type: Tubular adenocarcinoma Histologic grade: Moderately differentiated Tumor extent: Muscularis propria Lymph nodes: Not
specified Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified
Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

Source: NCI Genomic Data Commons file 54d9e27e-2030-462f-a7ba-4e0feabdf477 (TCGA-BR-4294.C0B39079-61D5-4081-A07A-D71ADB584FB5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).